Gene-level copy-number profile of tumor specimen AP-62LT-HJ from APOLLO case AP-62LT, project APOLLO-LUAD (APOLLO1: Proteogenomic characterization of lung adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Solid carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3.
Specimen AP-62LT-HJ: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c3cfbd73-f0ef-44c2-a6cf-a28422f029f7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator AP-62LT-PY (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,227 have no estimate.
https://portal.gdc.cancer.gov/files/194a0849-d868-44de-bce1-14ff27a50ea6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 935; copy number 2: 57,397; copy number 3: 55; copy number 4: 4.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:40,883,634–40,883,763, 1 gene: AL353626.2.
- chr10:42,149,310–42,149,549, 1 gene: KSR1P1.
- chr19:16,479,061–16,496,167, 1 gene (within-gene range 0–2): CALR3.
- chr21:10,649,400–13,016,692, 2 genes: IGHV1OR21-1, AP001464.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 833. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
